Gene-level copy-number profile of tumor specimen C3N-03186-01 from CPTAC case C3N-03186, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.8 years (20,009 days).
Specimen C3N-03186-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d5ce529-d142-492d-80fd-9fcefc444839.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03186-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/bc067ce4-4411-4e42-a5cd-0550495e30d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 2,647; copy number 2: 48,488; copy number 3: 7,153; copy number 4: 3; copy number 5: 2; copy number 11: 3; copy number 18: 5; copy number 20: 1; copy number 21: 2; copy number 22: 9.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,409,009–23,438,700, 80 genes (broad region; genes not listed).
- chr9:39,191,100–39,191,360, 1 gene (within-gene range 0–1): RN7SL640P.
- chr9:40,121,962–40,153,147, 3 genes: CDRT15P14, AL773545.1, AL773545.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–4,792,534, 5 genes, copy number 18: LINC01777, Z98747.1, LINC01646, AJAP1, Z98886.1.
- chr3:179,101,366–179,341,887, 7 genes, copy number 22: AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1.
- chr3:186,900,198–186,922,753, 2 genes, copy number 21: RPS20P14, AC007690.1.
- chr9:39,734,670–39,741,193, 2 genes, copy number 5: RAB28P1, RBPJP5.
- chr20:16,177,933–16,259,603, 2 genes, copy number 22: AL161941.1, PPIAP17.
- chr20:39,329,014–39,329,924, 1 gene, copy number 20: ATG3P1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 11 (within-gene range 2–11): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 2,647. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
